Gene-level copy-number profile of tumor specimen TCGA-C5-A1ME-01A from TCGA case TCGA-C5-A1ME, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 41.0 years (14,970 days).
Specimen TCGA-C5-A1ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.24044c33-3461-4c15-8444-e15025ec9de6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1ME-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8c47f0e-4cd5-46f9-9cd5-24bab8091e34

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 14,345; copy number 3: 35,274; copy number 4: 8,161; copy number 5: 429; copy number 6: 121; copy number 7: 1,163; copy number 9: 171; copy number 10: 134; copy number 11: 9; copy number 20: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1ME-01A-11D-A13V-01): tumor purity 0.73, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,478 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–39,889,059, 616 genes, copy number 7–10 (broad region; genes not listed).
- chr5:51,101,172–51,886,769, 10 genes, copy number 11–20: AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182.
- chr12:66,767–34,249,958, 850 genes, copy number 7 (broad region; genes not listed).
- chr15:27,754,875–28,099,315, 1 gene, copy number 7 (within-gene range 3–7): OCA2.
- chr15:27,895,704–27,896,582, 1 gene, copy number 7: RPL5P32.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
